CCDI case PBBPMT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/77400ff9-0aca-4316-80c9-9f2f157615dd

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.3 years (4,506 days).

Biospecimens (3 samples)
- Sample 0DEHN1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHNV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEHPI: Tissue type: Tumor; Specimen type: Solid Tissue.
